Somatic mutation profile of tumor specimen BA2660D (aliquot aq-BA2660D) from BEATAML1.0 case 2170, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 44.0 years (16,053 days).
Specimen BA2660D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5460357a-b404-4746-826f-4aed2baa5560.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2591D (Solid Tissue Normal), aliquot aq-BA2591D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fc736a4-8f7b-4754-8504-fdbed415f676

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABI3BP | c.2777C>G p.A926G | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- DAAM2 | c.3075C>A p.D1025E (on ENST00000274867 / NM_001201427.2; = p.D1024E on NM_015345.3) | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2
- DGKH | c.95C>A p.A32E | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.003); called by muse, mutect2
- LAMB2 | c.2483G>T p.C828F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- UCK1 | c.366G>T p.R122S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.72); called by muse, mutect2
